Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6003, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6003-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) LEFT PARTIAL GLOSSECTOMY:

DEEPLY INVASIVE SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED (2.8 CM).

No perineural invasion or lymphovascular invasion identified.

Surgical margins of resection, no tumor present.

Growth: Ulcerating.

(B) LEFT SUPRAOMOHYOID NECK DISSECTION LEVEL I:

Six lymph nodes, no tumor present (0/6).

(C) LEFT SUPRAOMOHYOID NECK DISSECTION LEVEL II:

One lymph node, no tumor present (0/1).

(D) LEFT SUPRAOMOHYOID NECK DISSECTION LEVEL III:

MICROSCOPIC FOCUS OF CARCINOMA (SUBCAPSULAR) IN ONE OF SIXTEEN LYMPH NODES (1/16).

(E) TOOTH #5:

Tooth, gross examination only.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) LEFT PARTIAL GLOSSECTOMY - One partial glossectomy (9.6 x 3.2 x 0.9 cm) is oriented by suture single stitch for anterior, double stitch for dorsal surface. One ulcerated tumor (2.8 x 1.5 x 1.0 cm) is 0.3 cm away from closest anterior margin. The specimen is entirely submitted in thirteen cassettes. (some tissue submitted for tissue bank).

INK CODE: Black - anterior with deep margin area.

SECTION CODE: A1, A2, anterior and deeper margin for frozen section; A3, inferior margin en face; A4, posterior margin en face; A5, dorsal margin en face; A6-A12, rest of tumor and surrounding tissue from anterior to posterior circumferences.

*FS/DX: FAVOR SQUAMOUS CELL CARCINOMA, MARGIN IS FREE.

(B) LEFT SUPRAOMOHYOID NECK DISSECTION LEVEL I - Received is a portion of yellow-tan fibrofatty adipose tissue including submandibular gland and a short segment of venous tissue measuring 6.8 x 3.5 x 1.6 cm. The submandibular gland measures 3.6 x 3.2 x 1.5 cm. The venous structure measures approximately 3.5 cm in length and 0.2 cm in diameter. Submandibular gland is step sectioned at close intervals revealing no gross abnormalities. The venous structure section revealing no evidence of tumor. The remainder of the tissue is dissected revealing six possible lymph nodes that range from 0.4 to 0.8 cm. Representative sections are submitted in cassette B1-B9.

SECTION CODE: B1, ends of venous tissue; B2-B4, representative sections of submandibular gland; B5, highest lymph node unsectioned; B6, single node bisected; B7, single node sectioned; B8, two small lymph nodes; B9, lowest lymph node unsectioned.

(C) LEFT SUPRAOMOHYOID NECK DISSECTION, LEVEL II - Received is a portion of yellow-tan fibrofatty adipose tissue measuring 3.2 x 1.8 x 1.9 cm. There is a short segmented attached portion of venous tissue measuring 1.4 cm in length and 0.3 cm in diameter. The venous tissue reveals no evidence of tumor. Four possible lymph nodes are identified on sectioning the adipose tissue that range from 0.3 to 0.4 cm. Representative sections are submitted in cassettes C1 and C2.

[page 2 of 2]
SECTION CODE: C1, sections of venous tissue; C2, four small lymph nodes, [REDACTED]
(D) LEFT SUPRAOMOHYOID NECK DISSECTION, LEVEL III - Received is a portion of yellow-tan fibrofatty adipose tissue measuring 3.2 x 2.2 x 1.8 cm. The tissue was dissected revealing seventeen possible lymph nodes that range from 0.4 to 1.7 cm. Representative sections are submitted in cassette D1-D8

SECTION CODE: D1, four small lymph nodes; D2, four small lymph nodes; D3, four small lymph nodes; D4, single node bisected; D5, single node trisected; D6, single node trisected; D7, single node sectioned; D8, single node sectioned.
[REDACTED]

(E) TOOTH #5 - Received is a tooth 1.6 x 0.9 x 0.8 cm. Specimen submitted for gross only. [REDACTED]

CLINICAL HISTORY

The patient has a history of oral cancer.

SNOMED CODES

T-53000, T-C4200, M-80703

*Some tests reported here may have been developed and performance characteristics determined by [REDACTED] Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration.

Released by [REDACTED]

Source: NCI Genomic Data Commons file 608a90cb-8ba2-4e97-9cdf-1252c255f695 (TCGA-CV-6003.6AE06A67-BAC0-4884-A7A8-ACA62CC81074.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).